Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5113, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5113-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, RIGHT, RADICAL NEPHRECTOMY –

- A. RENAL CELL CARCINOMA, CLEAR CELL TYPE.
- B. THE CARCINOMA MEASURES 13.7 CM IN GREATEST DIMENSION AND IS PREDOMINANTLY CONFINED TO THE UPPER POLE.
- C. THE TUMOR INVOLVES THE PERIRENAL SOFT TISSUE.
- D. FUHRMAN NUCLEAR GRADE IS 2/4.
- E. ANGIOLYMPHATIC INVASION IS NOT IDENTIFIED.
- F. ADRENAL GLAND IS PRESENT AND IS NOT INVOLVED BY TUMOR.
- G. TNM STAGE: T3a N0 MX.
- H. NON-NEOPLASTIC KIDNEY WITH MILD CHRONIC INTERSTITIAL INFLAMMATION.
- I. THREE PERIHILAR LYMPH NODES, NEGATIVE FOR TUMOR.

Source: NCI Genomic Data Commons file 333457b1-7de4-4226-8d81-654d876bccd0 (TCGA-B0-5113.29B597E0-79BF-4C4C-962E-EA146CF0812A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).